Gene-level copy-number profile of tumor specimen TCGA-DX-A3M2-01A from TCGA case TCGA-DX-A3M2, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 59.4 years (21,689 days).
Specimen TCGA-DX-A3M2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.c2ac4d7c-9026-4e15-bbfb-fda0f7255c6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3M2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/387b96c6-04b7-4606-a227-3d402b9085ba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 830; copy number 2: 13,260; copy number 3: 15,948; copy number 4: 17,139; copy number 5: 6,921; copy number 6: 2,717; copy number 7: 655; copy number 8: 1,231; copy number 9: 116; copy number 10: 258; copy number 11: 161; copy number 13: 96; copy number 14: 123; copy number 15: 10; copy number 16: 63; copy number 18: 61; copy number 19: 66; copy number 20: 124.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3M2-01A-21D-A227-01): tumor purity 0.24, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,098,660–13,323,450, 14 genes: AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1.
- chr9:13,406,380–13,488,125, 1 gene (within-gene range 0–1): LINC01235.
- chr9:21,994,139–23,849,914, 20 genes: CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,078 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:2,921,496–45,895,970, 625 genes, copy number 10–20 (broad region; genes not listed).
- chr7:14,145,049–14,974,777, 1 gene, copy number 10 (within-gene range 6–10): DGKB.
- chr7:14,814,131–21,945,903, 87 genes, copy number 9–16 (broad region; genes not listed).
- chr7:34,346,512–38,932,394, 96 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr8:47,260,878–49,907,446, 41 genes, copy number 9 (within-gene range 6–9): SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1.
- chr17:3,116,427–6,375,080, 137 genes, copy number 11 (broad region; genes not listed).
- chr19:20,416,514–22,555,367, 91 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
